Gene-level copy-number profile of tumor specimen TCGA-BA-A6DE-01A from TCGA case TCGA-BA-A6DE, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 70.8 years (25,874 days).
Specimen TCGA-BA-A6DE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.e8999a21-6079-405c-8060-a2392c10561a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-A6DE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aa1feca1-fd24-46aa-94fe-ab790b93fd1c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 19,242; copy number 2: 36,054; copy number 3: 3,507; copy number 4: 955; copy number 5: 20; copy number 7: 19; copy number 11: 6; copy number 13: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-A6DE-01A-22D-A31K-01): tumor purity 0.67, ploidy 1.8, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 55 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:193,730,555–195,540,287, 17 genes, copy number 7: SEC61GP1, AC074290.1, AC068135.2, AC068135.1, GLULP6, HNRNPA1P47, LINC01821, AC106883.1, AC073973.1, Metazoa_SRP, AC006196.1, LINC01790, AC010983.1, AC104823.1, AC064834.1, RNU6-169P, LINC01825.
- chr2:199,867,396–200,482,264, 10 genes, copy number 13 (within-gene range 2–13): AC097717.1, AC108032.1, RN7SL717P, C2orf69, TYW5, MAIP1, AC004464.1, SPATS2L, RNY4P34, AC012459.1.
- chr7:57,404,172–57,777,521, 20 genes, copy number 5 (within-gene range 3–5): AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1, NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2.
- chr8:33,969,567–34,874,633, 8 genes, copy number 7–11: AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1.

Autosomal genes at a single copy (total copy number 1): 16,821. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
